Gene-level copy-number profile of tumor specimen ALCH-AE71-TTR1-A from ALCHEMIST case ALCH-AE71, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 60.0 years (21,926 days).
Specimen ALCH-AE71-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file eefef7e9-2f90-4210-9dc2-42c98f8a892d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE71-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,752 have no estimate.
https://portal.gdc.cancer.gov/files/af8821f5-e1c8-4bb5-9150-ad537735a3c8

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 651; copy number 1: 30,999; copy number 2: 24,190; copy number 3: 1,280; copy number 4: 1,610; copy number 5: 13; copy number 6: 61; copy number 8: 67.

Homozygous deletions (total copy number 0; autosomes only): 68 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,616,836–10,617,115, 1 gene (within-gene range 0–1): RN7SL614P.
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–1): AL139423.1.
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–1): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr3:46,835,111–47,009,704, 5 genes: MYL3, PTH1R, AC109583.3, CCDC12, NBEAL2.
- chr3:75,384,059–75,590,649, 11 genes: AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1.
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–1): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr6:34,537,802–34,556,333, 1 gene: SPDEF.
- chr8:12,087,396–12,175,771, 7 genes (within-gene range 0–1): RNA5SP253, DEFB108D, ZNF705D, AC130366.1, USP17L7, USP17L2, FAM90A2P.
- chr21:7,744,962–8,454,792, 26 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 3,031 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,626,787–204,127,743, 16 genes, copy number 3: ATP2B4, NSA2P1, SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, LINC00303, AL592146.2, SOX13.
- chr2:9,951,693–10,022,825, 3 genes, copy number 3: GRHL1, AC010969.1, AC104794.4.
- chr2:60,719,640–66,392,450, 135 genes, copy number 3 (broad region; genes not listed).
- chr3:129,998,531–198,123,232, 1,160 genes, copy number 3–4 (broad region; genes not listed).
- chr7:65,141,032–65,463,438, 9 genes, copy number 4 (within-gene range 2–4): INTS4P1, AC104073.2, AC104073.1, AC104073.4, AC104073.3, RSL24D1P3, AC092685.1, ZNF92, AC114501.3.
- chr7:76,087,444–76,505,995, 14 genes, copy number 3: RNU6-863P, GTF2IP7, AC005077.2, AC005077.1, AC005077.3, SRRM3, HSPB1, YWHAG, PPIAP81, SSC4D, ZP3, DTX2, FDPSP2, AC005522.1.
- chr8:36,277,763–38,063,791, 42 genes, copy number 3: MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1.
- chr9:61,190,003–64,082,534, 76 genes, copy number 3–5 (broad region; genes not listed).
- chr9:104,970,593–114,099,291, 147 genes, copy number 3 (broad region; genes not listed).
- chr9:137,605,744–137,711,018, 1 gene, copy number 3 (within-gene range 2–3): AL590627.2.
- chr9:137,618,992–137,870,016, 1 gene, copy number 3 (within-gene range 2–3): EHMT1.
- chr9:137,776,539–138,253,217, 10 genes, copy number 3: AL590627.1, MIR602, AL772363.1, CACNA1B, AL591424.1, IL9RP1, TUBBP5, AL591424.2, AL954642.1, FAM157B.
- chr13:114,234,887–114,337,626, 7 genes, copy number 3: CDC16, MIR548AR, MIR4502, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr14:18,333,726–19,936,757, 82 genes, copy number 3 (broad region; genes not listed).
- chr14:22,123,318–22,190,713, 9 genes, copy number 3: TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33.
- chr14:22,202,583–22,272,563, 6 genes, copy number 3: TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1.
- chr14:26,598,369–26,806,467, 1 gene, copy number 4: LINC02588.
- chr14:26,775,495–26,836,458, 2 genes, copy number 4: LINC02294, LINC02293.
- chr14:26,908,642–26,908,725, 1 gene, copy number 4 (within-gene range 1–4): MIR4307.
- chr16:32,649,193–32,678,831, 5 genes, copy number 3: AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3.
- chr16:32,845,964–32,873,128, 3 genes, copy number 3: AC142086.2, IGHV2OR16-5, BCAP31P2.
- chr16:33,094,204–33,462,249, 15 genes, copy number 4 (within-gene range 2–4): HERC2P8, AC145350.4, AC145350.1, ABHD17AP9, AC138869.1, AC138869.2, TP53TG3C, AC138869.3, AC141257.2, TP53TG3E, AC141257.3, TP53TG3B, AC141257.1, AC141257.4, TP53TG3F.
- chr16:84,053,761–84,178,767, 6 genes, copy number 3 (within-gene range 2–3): MBTPS1, AC040169.3, AC040169.1, AC040169.2, HSDL1, DNAAF1.
- chr18:45,034–28,177,946, 502 genes, copy number 3–4 (broad region; genes not listed).
- chr18:77,421,619–77,561,044, 3 genes, copy number 3: AC124254.2, AC124254.1, BDP1P.
- chr19:27,681,072–34,471,251, 140 genes, copy number 3–4 (broad region; genes not listed).
- chr19:36,604,817–40,576,464, 190 genes, copy number 4–8 (within-gene range 2–8) (broad region; genes not listed).
- chr20:32,277,651–32,439,319, 3 genes, copy number 4: KIF3B, AL121583.1, ASXL1.
- chr20:32,631,625–40,126,357, 223 genes, copy number 3–5 (broad region; genes not listed).
- chr22:15,282,557–18,947,732, 150 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr22:27,978,014–28,679,865, 1 gene, copy number 3 (within-gene range 2–3): TTC28.
- chr22:28,056,153–30,240,538, 61 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr22:30,262,829–30,378,658, 7 genes, copy number 3 (within-gene range 2–3): OSM, AC004264.2, CASTOR1, AC004997.1, TBC1D10A, SF3A1, CCDC157.

Autosomal genes at a single copy (total copy number 1): 28,828. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
